Somatic mutation profile of tumor specimen TCGA-P8-A6RY-01A (aliquot TCGA-P8-A6RY-01A-12D-A35D-08) from TCGA case TCGA-P8-A6RY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 55.1 years (20,109 days).
Specimen TCGA-P8-A6RY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bacaf58-c76e-4556-9208-16d8a5fdaac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P8-A6RY-10A (Blood Derived Normal), aliquot TCGA-P8-A6RY-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4cd7c5f-2eaa-49c2-aa83-86b4e61884b6

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LONP1 | c.2869G>T p.V957L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs771871770, COSV56798159; called by muse, mutect2, varscan2
- ARHGAP22 | c.563T>A p.L188H | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELANE | c.327C>T p.Y109= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1339843779; called by muse, mutect2, varscan2
- HMGA2 | c.120C>T p.T40= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs552619480, COSV63591536; called by muse, mutect2, varscan2
- OPA3 | c.399C>T p.L133= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1351919794, COSV99840839; called by muse, mutect2, varscan2
